Somatic mutation profile of tumor specimen TCGA-UC-A7PG-06A (aliquot TCGA-UC-A7PG-06A-11D-A42O-09) from TCGA case TCGA-UC-A7PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 44.4 years (16,231 days).
Specimen TCGA-UC-A7PG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf896f9f-853f-4cee-8f97-44d8820dd924.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UC-A7PG-11C (Solid Tissue Normal), aliquot TCGA-UC-A7PG-11C-11D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5d524c9-9788-4200-8f1f-967a40a69f28

The open-access MAF lists 247 somatic variants for this specimen: 164 protein-altering or splice-affecting, 72 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 72, Nonsense Mutation 15, RNA 5, Intron 3, Splice Region 2, 3'UTR 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs761160403, COSV52223910; called by muse, mutect2, varscan2
- ABCD1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as CM000641, COSV99497224; called by muse, mutect2
- ABHD6 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99916888; called by muse, mutect2, varscan2
- ACP3 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60485239; called by muse, mutect2, varscan2
- ADAMTS20 | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV101166063; called by muse, mutect2
- ADAMTSL3 | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs141060865; called by muse, mutect2, varscan2
- ADCY1 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99811225; called by muse, mutect2
- AIFM1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.752); catalogued as COSV99780733; called by muse, mutect2, varscan2
- ANKLE2 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100513913, COSV100514108; called by muse, mutect2, varscan2
- ANXA2 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100221868; called by muse, mutect2, varscan2
- APOC4-APOC2 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99376896; called by muse, mutect2, varscan2
- AREL1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV100707555; called by muse, mutect2, varscan2
- ARMC8 | c.1141G>C p.E381Q (on ENST00000469044 / NM_001363941.2; = p.E367Q on NM_015396.6) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100509397; called by muse, mutect2
- ASCC3 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100225182; called by muse, mutect2, varscan2
- ASXL2 | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1005263447, COSV99710145; called by muse, mutect2
- ATF7IP2 | c.1415C>G p.S472* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100202506; called by muse, mutect2, varscan2
- ATP6V1A | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.251); catalogued as COSV99849838; called by muse, mutect2, varscan2
- BPIFB4 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100971414; called by muse, mutect2, varscan2
- BRCA1 | c.5464C>A p.H1822N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.523); catalogued as COSV100523268, COSV58793741; called by muse, mutect2, varscan2
- CACNA1B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1034554149, COSV99495105; called by muse, mutect2, varscan2
- CAMP | c.130C>T p.R44C (on ENST00000296435; = p.R41C on NM_004345.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs367676545; called by muse, varscan2
- CAPN12 | c.1077C>G p.F359L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100184942, COSV100185060; called by muse, mutect2, varscan2
- CD180 | c.1968G>C p.W656C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV56520150, COSV99842077; called by muse, mutect2, varscan2
- CDC123 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99826657; called by muse, mutect2, varscan2
- CDC20B | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.165); catalogued as COSV99696486; called by muse, mutect2, varscan2
- CERS1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1161008712, COSV99896784; called by muse, mutect2, varscan2
- CES1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 47/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369300055, COSV100828554; called by muse, mutect2, varscan2
- CHRNA5 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100213770; called by muse, mutect2, varscan2
- CHRND | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99285504; called by muse, mutect2, varscan2
- CIP2A | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99842610; called by muse, mutect2, varscan2
- CLCN4 | c.2190C>T p.S730= | Splice Region (SNP) | VAF 12/51 reads (24%) | catalogued as rs778033301, COSV66466769; called by muse, mutect2, varscan2
- CNTRL | c.6917C>G p.S2306C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs965041473, COSV99441046; called by muse, mutect2, varscan2
- COL4A5 | c.2885C>G p.S962* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100086438; called by muse, mutect2, varscan2
- CORO2B | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs148459295; called by muse, mutect2, varscan2
- CRB1 | c.2129-1G>C p.X710_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV66329889, COSV66331406; called by muse, mutect2
- CSDC2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs767371689, COSV99348021; called by muse, mutect2, varscan2
- CTNND2 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs772760179, COSV100471543; called by muse, mutect2, varscan2
- CYB5R4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.328); catalogued as COSV100859631; called by muse, mutect2, varscan2
- CYP11B1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267601810, CM147559, COSV99454509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEFA4 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868137471; called by muse, mutect2
- DMXL1 | c.7609C>T p.L2537F | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100223219, COSV60704657; called by muse, mutect2
- EFHC2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV101375434, COSV69552768; called by muse, mutect2, varscan2
- EIF4B | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs753615463, COSV50401645; called by muse, mutect2, varscan2
- EPB41L2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377029691; called by muse, varscan2
- EPC1 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99552534; called by muse, mutect2, varscan2
- EPHA8 | c.2020A>T p.T674S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99384184; called by muse, mutect2, varscan2
- ETS1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100090004; called by muse, mutect2, varscan2
- EXO5 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV56415858, COSV99591198; called by muse, mutect2, varscan2
- FAAH | c.954C>G p.V318= | Splice Region (SNP) | VAF 27/62 reads (44%) | catalogued as rs750300015, COSV99679864; called by muse, mutect2, varscan2
- FAM3D | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs149077834; called by mutect2, varscan2
- FLG | c.4258C>A p.Q1420K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV100910480; called by muse, mutect2, varscan2
- FST | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs202174134, COSV56814987; called by muse, mutect2, varscan2
- GALNT11 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs765599528, COSV57427334; called by muse, mutect2, varscan2
- GNA15 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1396214838, COSV53585766; called by muse, mutect2, varscan2
- GNAS | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as CD920862, COSV55673978; called by muse, mutect2, varscan2
- GOLGA4 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs755889799, COSV100728646; called by muse, mutect2, varscan2
- GPR107 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.732); catalogued as rs200754726, COSV61277037; called by muse, mutect2, varscan2
- GRM7 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63159440; called by muse, mutect2
- HDGF | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as COSV100625580; called by muse, mutect2, varscan2
- HS1BP3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs569287360, COSV100397784; called by muse, mutect2, varscan2
- HSCB | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV99319644; called by muse, mutect2, varscan2
- HSD3B1 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV99347797; called by muse, mutect2, varscan2
- HTR6 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs760097478, COSV99229869; called by muse, mutect2, varscan2
- IGSF1 | c.3113G>T p.C1038F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63841161; called by muse, mutect2, varscan2
- IQCG | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV99502019; called by muse, mutect2, varscan2
- KCNN4 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254533339, COSV99486926; called by muse, mutect2, varscan2
- KLHL13 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99450950; called by muse, mutect2, varscan2
- LIG4 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV100799690; called by muse, mutect2, varscan2
- LIMK1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV100282991; called by muse, mutect2, varscan2
- LMX1A | c.630C>G p.F210L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54228075, COSV99671605, COSV99673342; called by muse, mutect2, varscan2
- LRP2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs777216431, COSV99786454; called by muse, mutect2, varscan2
- LRRC49 | c.1790T>A p.V597E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as COSV99536910; called by muse, mutect2, varscan2
- LRTM2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs776606825, COSV54565369; called by muse, mutect2, varscan2
- LUC7L | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV53457933; called by muse, mutect2
- MACF1 | c.11041G>C p.E3681Q (on ENST00000372915; = p.E1614Q on NM_012090.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99241071; called by muse, mutect2, varscan2
- MBD5 | c.2593C>G p.L865V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV101289931; called by muse, mutect2
- MCF2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100644421; called by muse, mutect2, varscan2
- MDH2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782546937, COSV100242557; called by muse, mutect2, varscan2
- MDN1 | c.13738G>A p.E4580K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as rs1266681737, COSV101020742; called by muse, mutect2, varscan2
- MEGF8 | c.5884G>A p.E1962K (on ENST00000251268 / NM_001271938.2; = p.E1895K on NM_001410.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs1454888198, COSV52079694; called by muse, mutect2
- MORC4 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99716778; called by muse, mutect2, varscan2
- MSL3 | c.1494C>G p.F498L (on ENST00000312196 / NM_078629.4; = p.F332L on NM_006800.4) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100384523, COSV56492058; called by muse, mutect2, varscan2
- MTMR4 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV100050749; called by muse, mutect2
- MUC5B | c.10484C>A p.P3495Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101500022; called by muse, mutect2, varscan2
- NISCH | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100617112; called by muse, mutect2, varscan2
- NKRF | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV100441409; called by muse, mutect2, varscan2
- NLRP13 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.261); catalogued as rs774137332, COSV61624021; called by muse, mutect2, varscan2
- NMT2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV65382740; called by muse, mutect2, varscan2
- NUDT19 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101229177, COSV67959592; called by muse, mutect2, varscan2
- OR2L3 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100741909; called by muse, varscan2
- OR51B4 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100970557, COSV66517755; called by muse, mutect2, varscan2
- OR7G2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100560318; called by muse, mutect2, varscan2
- PADI2 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs765325408, COSV64946144; called by muse, mutect2
- PALM2AKAP2 | c.979C>T p.R327C (on ENST00000259318 / NM_001136562.3; = p.R558C on NM_007203.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376308694; called by muse, mutect2, varscan2
- PCDH15 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751941551, CM165391, COSV57288231, COSV57352576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB14 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.151); catalogued as COSV99505520; called by muse, mutect2, varscan2
- PCDHB14 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV99505522; called by muse, mutect2, varscan2
- PCYT1A | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs746655391, COSV99491923; called by muse, mutect2, varscan2
- PDE4B | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302159; called by muse, mutect2
- PDXK | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV99376037; called by muse, mutect2
- PHLDA1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.509); catalogued as rs982542267, COSV99876514; called by muse, mutect2
- PHRF1 | c.1380G>C p.K460N (on ENST00000264555 / NM_001286581.2; = p.K459N on NM_020901.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99199454; called by muse, mutect2, varscan2
- PKD1L1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1394070930, COSV99218346; called by muse, mutect2, varscan2
- PLCE1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV53347562, COSV99593434; called by muse, mutect2, varscan2
- PLEKHM1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs541756972, COSV101378668, COSV101378803; called by muse, mutect2, varscan2
- PLG | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99804220; called by muse, mutect2
- PPP4R3A | c.2048T>G p.F683C (on ENST00000554943 / NM_001366432.1; = p.F670C on NM_001284280.1) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100465553; called by muse, mutect2, varscan2
- PRDM5 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs781674958, COSV53359186; called by muse, mutect2, varscan2
- PTPRA | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV99399124; called by muse, mutect2, varscan2
- PTPRM | c.1271G>C p.G424A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100154721; called by muse, mutect2, varscan2
- PTPRU | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867290552, COSV60534846; called by mutect2, varscan2
- RARB | c.1027G>A p.E343K (on ENST00000383772 / NM_001290216.2; = p.E336K on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV51970894, COSV99979096; called by muse, mutect2, varscan2
- RFXAP | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.932); catalogued as rs1172888518, COSV99715111; called by muse, mutect2, varscan2
- RIC1 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99316628; called by muse, mutect2, varscan2
- RPS6KC1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100873759; called by muse, mutect2, varscan2
- SAMSN1 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV99580631; called by muse, mutect2, varscan2
- SAXO2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100255555; called by muse, mutect2, varscan2
- SCARA3 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.243); catalogued as COSV57269607; called by muse, mutect2, varscan2
- SERPINB9 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV101046451; called by muse, varscan2
- SLC20A2 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100645991; called by muse, mutect2, varscan2
- SLC44A2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355261894, COSV59836055, COSV59838669; called by muse, mutect2, varscan2
- SMC2 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99658307; called by muse, mutect2, varscan2
- SMC5 | c.3254T>G p.L1085* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100746951; called by muse, mutect2, varscan2
- SPACA1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.085); catalogued as COSV52760325; called by muse, mutect2, varscan2
- SPG7 | c.1774C>G p.R592G (on ENST00000268704; = p.R599G on NM_003119.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244542; called by muse, mutect2, varscan2
- STAB1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs558150044, COSV100401186; called by muse, varscan2
- STAG2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.621); catalogued as COSV99492231; called by muse, mutect2
- STS | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV54270807; called by muse, mutect2, varscan2
- SUN3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs1229088173, COSV99813805; called by muse, mutect2, varscan2
- SUPT5H | c.2672C>T p.S891F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100781902; called by muse, mutect2, varscan2
- SYNE2 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV100646642; called by muse, mutect2, varscan2
- SYNM | c.4435G>A p.A1479T (on ENST00000336292 / NM_145728.3; = p.A1167T on NM_015286.6) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as COSV100018358; called by muse, mutect2
- SYNPO2L | c.1072G>A p.D358N (on ENST00000394810 / NM_001114133.3; = p.D134N on NM_024875.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100866305; called by muse, mutect2, varscan2
- TCEAL3 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV99685217; called by muse, mutect2
- THBS1 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs777305100, COSV99527559; called by muse, mutect2, varscan2
- TIAM1 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99732493, COSV99732686, COSV99736194; called by muse, mutect2, varscan2
- TMEM266 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs1045911513, COSV101189557, COSV66379874; called by muse, mutect2, varscan2
- TMEM63A | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753026260, COSV100834245; called by muse, mutect2, varscan2
- TNKS | c.3686G>A p.G1229E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100126079; called by muse, mutect2, varscan2
- TNS2 | c.206G>A p.R69K (on ENST00000314250 / NM_170754.4; = p.R79K on NM_015319.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV100047405; called by muse, mutect2, varscan2
- TOE1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1262701120, COSV100517041; called by mutect2, varscan2
- TRNAU1AP | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs772628492, COSV100867820; called by muse, mutect2, varscan2
- TUSC3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV101140356; called by muse, mutect2, varscan2
- UBR5 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99639272; called by muse, mutect2, varscan2
- UNC13D | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99255986; called by muse, mutect2, varscan2
- WASHC4 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100162023; called by muse, mutect2, varscan2
- WDR17 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54574336; called by muse, mutect2, varscan2
- WSCD1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100496370; called by muse, mutect2, varscan2
- XK | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781856258, COSV66120998; called by muse, mutect2, varscan2
- YARS1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as COSV100993239; called by muse, mutect2, varscan2
- ZFP28 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100019239; called by muse, mutect2
- ZIM2 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99687177; called by muse, mutect2, varscan2
- ZNF254 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV61643750; called by muse, mutect2, varscan2
- ZNF324B | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100351506; called by muse, varscan2
- ZNF366 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100574061; called by muse, mutect2, varscan2
- ZNF667 | c.1320G>C p.E440D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99410023; called by muse, mutect2, varscan2
- ZNF675 | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100704888; called by muse, mutect2, varscan2
- ZNF70 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100558821; called by muse, mutect2
- ZNF768 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1176774306, COSV63320979; called by muse, mutect2, varscan2
- ZNF792 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs375658175, COSV68692896; called by muse, mutect2, varscan2
- ZNF83 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99991146; called by muse, mutect2, varscan2
- CT45A1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 32/480 reads (7%) | called by muse, mutect2
- DLG3 | c.1666G>T p.E556* (on ENST00000374360 / NM_021120.4; = p.E219* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PTPRM | c.2877C>G p.I959M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2
- AADAC | c.237C>T p.V79= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV99233065; called by muse, mutect2, varscan2
- ABO | c.807C>T p.F269= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs782473555, COSV71743701; called by muse, varscan2
- ACSM4 | c.45C>T p.L15= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs758002942, COSV101257006; called by muse, mutect2, varscan2
- ACVR1B | c.444C>G p.V148= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99231255; called by muse, mutect2
- ADAD2 | c.1751G>A p.*584= (on ENST00000315906 / NM_001145400.2; = p.*666= on NM_139174.4) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs764884900, COSV99235061; called by muse, mutect2, varscan2
- ADAMTSL2 | c.468C>T p.D156= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs746513236, COSV100618882; called by muse, mutect2, varscan2
- C16orf71 | c.324G>A p.Q108= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV54794890; called by muse, mutect2, varscan2
- CACNA1A | c.2232G>A p.Q744= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV64203883; called by muse, mutect2, varscan2
- CADPS2 | c.1806G>A p.Q602= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100460662; called by muse, mutect2, varscan2
- CD1C | c.42A>T p.P14= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100939348; called by muse, mutect2
- CDH10 | c.360G>A p.E120= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1197447187, COSV100049975; called by muse, mutect2
- CDH20 | c.2166C>G p.V722= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99404261; called by muse, mutect2, varscan2
- CEACAM4 | c.60C>T p.I20= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV55730949, COSV99032678; called by muse, mutect2, varscan2
- CENPI | c.999G>C p.L333= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV99515002; called by muse, mutect2, varscan2
- CHIC1 | c.54G>A p.E18= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100998213; called by muse, mutect2, varscan2
- CHST6 | c.564C>T p.L188= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV59999959, COSV60002189; called by muse, mutect2, varscan2
- COL4A4 | c.1374A>T p.I458= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100306172; called by muse, mutect2, varscan2
- CRTAM | c.924C>T p.F308= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99911747; called by muse, mutect2
- ERBB3 | c.3093C>T p.L1031= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99915700; called by muse, mutect2
- ERBB3 | c.3546C>A p.L1182= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99915702; called by muse, mutect2, varscan2
- ERGIC2 | c.618C>T p.V206= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as COSV100791934; called by muse, mutect2, varscan2
- HEG1 | c.1338C>T p.V446= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs771255321, COSV60763007; called by muse, mutect2, varscan2
- HID1 | c.324C>T p.I108= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100585934; called by muse, mutect2, varscan2
- KCNA3 | c.1242C>T p.S414= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV63901463; called by muse, mutect2, varscan2
- KIF13A | c.2718G>A p.P906= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs764103279, COSV52441725; called by muse, mutect2, varscan2
- LDHB | c.615G>C p.V205= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV100636375; called by muse, mutect2, varscan2
- LMO7 | c.4980C>T p.F1660= (on ENST00000357063; = p.F1341= on NM_005358.5) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100412403; called by muse, mutect2, varscan2
- LRRC37B | c.2655G>A p.Q885= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100495995; called by muse, mutect2, varscan2
- MMP21 | c.1149C>G p.L383= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100916660; called by muse, mutect2, varscan2
- MUC16 | c.11931C>T p.L3977= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs933904465, COSV67483810; called by muse, mutect2, varscan2
- MUC5B | c.10485A>T p.P3495= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101500023; called by muse, mutect2, varscan2
- MYO9B | c.2796G>A p.Q932= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV101261242; called by muse, mutect2, varscan2
- NSMAF | c.2274C>T p.A758= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs750073177, COSV50691187; called by muse, mutect2, varscan2
- PAQR9 | c.654C>T p.F218= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100503683; called by muse, mutect2, varscan2
- PCDHA11 | c.2187C>T p.G729= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV56484702; called by muse, mutect2, varscan2
- PDCD10 | c.174C>T p.L58= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs1274956108, COSV101208521, COSV67101973; called by muse, mutect2, varscan2
- POU6F2 | c.327G>C p.V109= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101302429, COSV68882999; called by muse, mutect2
- PRDX6 | c.483C>G p.L161= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100458583, COSV61165075; called by muse, mutect2
- PREX2 | c.540G>A p.L180= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99904880; called by muse, mutect2, varscan2
- PTCHD4 | c.717G>A p.V239= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs372931604; called by muse, mutect2, varscan2
- PYROXD1 | c.930C>T p.C310= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs977927618, COSV53708417; called by muse, mutect2, varscan2
- RB1CC1 | c.1563C>T p.V521= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs375834599, COSV99206009; called by muse, mutect2, varscan2
- RPUSD2 | c.192G>A p.K64= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100225080, COSV59766110; called by muse, mutect2, varscan2
- RTEL1 | c.2322C>T p.V774= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100541533; called by muse, mutect2, varscan2
- RTEL1 | c.2964G>A p.Q988= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1380817783, COSV100541534; called by muse, mutect2
- RTEL1 | c.2965C>A p.R989= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100541536; called by muse, mutect2, varscan2
- RTTN | c.4923C>T p.L1641= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55346655; called by muse, mutect2, varscan2
- RYR1 | c.11466G>A p.K3822= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100614380; called by muse, mutect2, varscan2
- SGSH | c.255G>A p.Q85= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100413312; called by muse, mutect2, varscan2
- SI | c.5359C>T p.L1787= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100013880; called by muse, mutect2, varscan2
- SLC25A43 | c.771G>A p.V257= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99474396; called by muse, mutect2, varscan2
- SLC4A8 | c.3021C>T p.L1007= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV60647139, COSV60648009; called by muse, mutect2
- SLC5A11 | c.1380G>A p.P460= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs774164600, COSV61741697; called by muse, mutect2, varscan2
- SLC6A14 | c.1068C>T p.L356= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV64148698; called by muse, mutect2, varscan2
- SLCO3A1 | c.483C>T p.P161= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs755280875, COSV100574888; called by muse, mutect2, varscan2
- SPAM1 | c.1200C>T p.L400= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as COSV99772678; called by muse, mutect2, varscan2
- SPIN2B | c.453C>G p.V151= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV52068861, COSV99328118; called by muse, mutect2, varscan2
- SRPK3 | c.603C>T p.Y201= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99472932; called by muse, mutect2, varscan2
- TBC1D4 | c.3405G>A p.E1135= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs540075377, COSV100884518; called by muse, mutect2, varscan2
- TBX22 | c.1122G>A p.K374= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100960603, COSV64785308; called by mutect2, varscan2
- TEX10 | c.2619C>T p.L873= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs191855673, COSV52440462; called by mutect2, varscan2
- TMEM182 | c.288C>T p.F96= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1314464949, COSV101305328, COSV101305364; called by muse, mutect2, varscan2
- TMPRSS9 | c.1491C>T p.S497= (on ENST00000648592; = p.S463= on NM_182973.2) | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs925594011; called by muse, mutect2
- TOPBP1 | c.4377G>A p.Q1459= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99604876; called by muse, mutect2, varscan2
- TRPM4 | c.2070C>T p.I690= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53261265, COSV99418977; called by muse, mutect2
- WFS1 | c.1737G>A p.L579= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs150970403, COSV56990240; called by muse, mutect2
- ZNF268 | c.390C>T p.I130= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs372724095; called by muse, mutect2, varscan2
- ZNF324B | c.444G>A p.L148= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100351507; called by muse, varscan2
- ZNF571 | c.894G>A p.Q298= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100143511, COSV100143695; called by muse, mutect2, varscan2
- ZNF74 | c.543C>G p.L181= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs766909600, COSV100677414, COSV100677560; called by muse, mutect2, varscan2
- ZSCAN20 | c.2868G>A p.E956= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100792482, COSV63681690; called by muse, mutect2
- ZW10 | c.486C>T p.L162= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99562424; called by muse, mutect2, varscan2
- AC244258.1 | n.903G>T | RNA (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- BIRC8 | n.1149C>G | RNA (SNP) | VAF 4/50 reads (8%) | catalogued as COSV101461289; called by muse, mutect2
- C14orf178 | n.568C>T | RNA (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100575638; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11557G>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51499142, COSV99173198; called by muse, mutect2, varscan2
- DCHS2 | n.4787G>A | RNA (SNP) | VAF 12/53 reads (23%) | catalogued as rs142512414; called by muse, mutect2, varscan2
- HNRNPK | c.1361+356G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100698865; called by muse, mutect2, varscan2
- LEKR1 | c.*1186G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100738565; called by muse, mutect2, varscan2
- NT5C1B-RDH14 | c.*157C>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101173280; called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570621 G>A | 5'Flank (SNP) | VAF 8/34 reads (24%) | catalogued as rs782570490; called by muse, mutect2, varscan2
- SH3KBP1 | c.521-3649G>A | Intron (SNP) | VAF 15/45 reads (33%) | catalogued as COSV101114302; called by muse, mutect2, varscan2
- SSPOP | n.15704G>A | RNA (SNP) | VAF 22/101 reads (22%) | catalogued as rs373429712; called by muse, mutect2, varscan2
